Somatic mutation profile of tumor specimen 0DW2WF from CCDI case PBCMMV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.5 years (5,664 days).
Specimen 0DW2WF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a259cfb-9c34-4ab2-8886-2ce6da87e4cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DW2VK (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e87bd330-a23a-4372-8743-d8bed4b5be51

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 2, Frame Shift Ins 1, Nonsense Mutation 1, Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAMK2A | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 40/720 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs986491632, COSV62246489, COSV62247198; called by muse, mutect2
- CFAP99 | c.712C>T p.R238* | Nonsense Mutation (SNP) | VAF 32/681 reads (5%) | catalogued as rs1373835096, COSV72648638; called by muse, mutect2
- ARID1A | c.6193dup p.A2065Gfs*34 | Frame Shift Ins (INS) | VAF 30/204 reads (15%) | called by mutect2, varscan2
- PDZD8 | c.615C>T p.A205= | Silent (SNP) | VAF 81/521 reads (16%) | catalogued as rs1475602121; called by muse, mutect2, varscan2
- ARNT2 | c.622+84T>C | Intron (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- CFAP65 | c.-2-93C>G | Intron (SNP) | VAF 6/123 reads (5%) | called by muse, mutect2
